Somatic mutation profile of tumor specimen 0DMN23 from CCDI case PBCANF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.9 years (6,182 days).
Specimen 0DMN23: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f79fa624-a661-42d1-9f93-3dadf65eda5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMN19 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0f1ca46-d9e0-407f-a7d8-013497b96f40

The open-access MAF lists 29 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 9, Intron 2, Frame Shift Del 2, In Frame Ins 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.103G>C p.G35R | Missense Mutation (SNP) | VAF 171/543 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as COSV64731793, COSV64731830, COSV64732212; called by muse, mutect2, varscan2
- ATRX | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 467/519 reads (90%) | catalogued as COSV64873866; called by muse, mutect2, varscan2
- CACNA1B | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760821629; called by muse, mutect2, varscan2
- CCDC74B | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 65/256 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763710118, COSV60100631; called by muse, mutect2, varscan2
- FAM160B1 | c.117G>T p.E39D | Missense Mutation (SNP) | VAF 288/725 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV65086238; called by muse, mutect2, varscan2
- LDLRAD3 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 304/724 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs754022854; called by muse, mutect2, varscan2
- MAP3K4 | c.4096G>A p.G1366R | Missense Mutation (SNP) | VAF 19/482 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815616, COSV62329900; called by muse, mutect2
- PLS1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 245/682 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs779525911, COSV104401397; called by muse, mutect2, varscan2
- ZDBF2 | c.5794C>T p.R1932C | Missense Mutation (SNP) | VAF 182/436 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1054355489, COSV65629622; called by muse, varscan2
- ACAD10 | c.324_325del p.C109Lfs*2 | Frame Shift Del (DEL) | VAF 194/510 reads (38%) | called by mutect2, varscan2
- MCM3 | c.1831G>A p.D611N (on ENST00000229854 / NM_001366374.2; = p.D601N on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 270/641 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- OR2A25 | c.874A>T p.R292W | Missense Mutation (SNP) | VAF 217/620 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, varscan2
- PCDH11Y | c.2882A>T p.K961M (on ENST00000400457 / NM_032973.2; = p.K950M on NM_032971.3) | Missense Mutation (SNP) | VAF 177/230 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDGFRA | c.1463_1483dup p.V488_E494dup | In Frame Ins (INS) | VAF 318/758 reads (42%) | called by mutect2, varscan2
- PDZD7 | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TBC1D4 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 34/444 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TP53 | c.708_715dup p.N239Tfs*11 | Frame Shift Ins (INS) | VAF 368/482 reads (76%) | called by mutect2, varscan2
- TRIP6 | c.26del p.P9Rfs*89 | Frame Shift Del (DEL) | VAF 62/213 reads (29%) | called by mutect2, varscan2
- ACTBL2 | c.192C>T p.G64= | Silent (SNP) | VAF 87/242 reads (36%) | catalogued as rs560370286; called by muse, mutect2, varscan2
- DYRK2 | c.651C>T p.H217= (on ENST00000344096 / NM_006482.3; = p.H144= on NM_003583.4) | Silent (SNP) | VAF 304/720 reads (42%) | catalogued as rs1409963245, COSV59847590; called by muse, mutect2, varscan2
- ECI1 | c.603G>A p.A201= | Silent (SNP) | VAF 160/351 reads (46%) | catalogued as rs200320472; called by muse, mutect2, varscan2
- EPHA1 | c.2385T>A p.P795= | Silent (SNP) | VAF 289/658 reads (44%) | called by muse, mutect2, varscan2
- FRAS1 | c.7422C>T p.T2474= | Silent (SNP) | VAF 178/694 reads (26%) | catalogued as rs759674249; called by muse, mutect2, varscan2
- IL18R1 | c.696C>T p.N232= | Silent (SNP) | VAF 218/500 reads (44%) | catalogued as rs11465644; called by muse, mutect2, varscan2
- ITGB6 | c.705T>C p.N235= | Silent (SNP) | VAF 155/495 reads (31%) | called by muse, mutect2, varscan2
- MSH4 | c.2403T>C p.D801= | Silent (SNP) | VAF 287/766 reads (37%) | catalogued as rs1463990127; called by muse, mutect2, varscan2
- PRAMEF12 | c.1200C>T p.T400= | Silent (SNP) | VAF 197/548 reads (36%) | catalogued as rs377321269; called by muse, mutect2, varscan2
- ADI1 | c.120+35G>C | Intron (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- RNF220 | c.1127-40G>A | Intron (SNP) | VAF 178/437 reads (41%) | catalogued as rs368455337; called by muse, mutect2, varscan2
